Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3526, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3526-01A (Primary Tumor).

*** Diagnosis/Diagnoses: ***

Colonic resection specimen (sigmoid) with a colon carcinoma of the histological type of a moderately differentiated adenocarcinoma, measuring 3 cm in its largest diameter and extending to a maximum of 11 cm from the resection margin. Invasive tumor spread to the level of the muscularis propria.

Oral and aboral margins tumor-free.

Ten mesocolic lymph nodes tumor-free and with uncharacteristically reactive changes.

Tumor stage therefore pT2 pn0 (0/10) L0 V0; G2.

*** Follow-up report: ***

A further lymph node preparation was performed subsequently after special fixation.

A further seven very small lymph nodes were detected as a result. Histologically the lymph nodes are tumor-free.

Lymph node status therefore pN0 (0/17)

Source: NCI Genomic Data Commons file dc7f4144-0fdb-42c0-9d62-ec345b0b1b2b (TCGA-AA-3526.7374CE91-8D9F-4BA3-867A-E326D2298077.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).